Surgical pathology report (de-identified scan), TCGA case TCGA-55-1596, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-1596-01A (Primary Tumor).

[page 1 of 4]
===== ADDENDUM REPORT #1; COMMENT: =====

Please see the modified below diagnosis to reflect the accurate lymph node count.

===== ADDENDUM REPORT #1; DIAGNOSIS: =====

A-D & F. SEE ORIGINAL DIAGNOSIS

E/EPC. LUNG, RIGHT UPPER LOBE, LOBECTOMY:

1-5, 7 & 8. SEE ORIGINAL DIAGNOSIS

6. REGIONAL LYMPH NODES: pN1, METASTATIC

ADENOCARCINOMA PRESENT IN ONE OF TWENTY-ONE LYMPH

1)

SURGICAL PATHOLOGY REPORT

===== SPECIMEN DESCRIPTION: =====

A. INFERIOR PULMONARY LIGAMENT LYMPH NODE

B. HILAR LYMPH NODE

C. TRACHEOBRONCHIAL ANGLE LYMPH NODE

D. SUBCARINAL LYMPH NODE

E. RIGHT UPPER LOBE OF LUNG, EPC

F. PROXIMAL BRONCHIAL LYMPH NODE

===== PRE-OPERATIVE DIAGNOSIS: =====

Right upper lobe of lung mass

===== POST-OPERATIVE DIAGNOSIS: =====

Lung carcinoma

===== CLINICAL INFORMATION: =====

Right upper lobe mass

===== INTRAOPERATIVE CONSULTATION: =====

EPC DIAGNOSIS: "(Gross) Proximal bronchial margin is grossly free of tumor"

by Dr. [REDACTED]

Tumor obtained for cancer genomics study.

[page 2 of 4]
==== GROSS DESCRIPTION: =====

A. Received in formalin are three irregular, partially cauterized fragments of tan-brown possible lymphoid tissue, ranging from 0.5 x 0.5 x 0.2 cm to 1.0 x 0.7 x 0.2 cm. The specimen is entirely submitted in one cassette.

B. Received in formalin is a 1.0 x 0.7 x 0.3 cm black-brown lymph node. The specimen is bisected. On sectioning, the cut surface is dark black and friable. The specimen is entirely submitted in one cassette.

C. Received in formalin are multiple irregular fragments of black-brown to yellow-tan soft tissue, ranging from 0.1 cm in greatest dimension to 1.0 x 0.5 x 0.3 cm. The specimen is entirely submitted in one cassette.

D. Received in formalin is a black-brown irregular lymph node, measuring 1.5 x 1.0 x 0.3 cm. On sectioning, the cut surface is gray-black and friable. The specimen is entirely submitted in one cassette.

E/EPC. The specimen is received in formalin and consists of a single lobe of lung, weighing 212 grams and measuring 15 x 14 x 14 cm in overall dimensions. The hilar region consists of two portions of bronchus, measuring 1.5 cm in length x 1.0 cm in diameter and 0.5 cm in length x 1.0 cm in diameter. There is also a 0.5 cm portion of vessel (the hilum). The structures are surrounded by six gray-black lymph nodes, ranging from 0.5 cm to 1.5 cm in greatest dimension. There are also two stapled resection margins at the hilum, measuring 7.5 cm in length and 2.0 cm in length. The stapled margins are trimmed and inked green. The hilar region is inked black. The pleural surface is purple-black with moderate anthracotic pigmentation. The surface is smooth with the exception of the 0.5 cm area of puckering on the lateral aspect. The pleural surface in this area is inked black. On sectioning, there is a well-circumscribed mass adjacent to the puckered area which measures 5 x 5 x 4.5 cm. The cut surface of the mass is yellow-tan soft and gritty with anthracotic pigmentation. The borders of the mass are rounded, serpiginous. The mass involves 40% of the cut surface and comes to within 1.0 cm of the vascular resection margin, 1.5 cm from the stapled resection margin, and 1.8 cm from the bronchial resection margin. The mass surrounds vascular and bronchial structures. On sectioning through the bronchus, the vessels are yellow-tan and smooth. There is no obvious involvement of the bronchial and vascular structures by the aforementioned mass. The mass abuts the inked pleural surface. The remainder of the specimen consists of mildly crepitant pink-red parenchyma. There is minimal anthracotic pigmentation. On sectioning, scattered gray-black intraparenchymal lymph nodes are identified (cassette 8). No additional masses or lesions are identified. Representative sections are submitted in ten cassettes as follows: cassette 1 - bronchial and vascular margins; cassette 2 - mass and portion of bronchus; cassette 3 - mass with vessel; cassette 4 - mass with inked pleural surface; cassette 5 - mass with surrounding uninvolved parenchyma; cassettes 6 through 8 - uninvolved parenchyma with the stapled resection margin in cassette 6; cassette 9 - one lymph node, bisected; cassette 10 - five lymph nodes.

[page 3 of 4]
[REDACTED]

F. Received in formalin is a 0.8 x 0.5 x 0.3 cm irregular gray-black lymph node. On sectioning, the cut surface is friable. The specimen is entirely submitted in one cassette.

[REDACTED]

==== MICROSCOPIC DESCRIPTION: =====

- A. One slide is evaluated, demonstrating fragments of a lymph node with extensive anthracosis (0/1). There is no evidence of malignancy.
- B. One slide is evaluated, demonstrating fragments of five lymph nodes with extensive anthracosis (0/5). There is no evidence of malignancy.
- C. One slide is evaluated, demonstrating fragments of four lymph nodes with extensive anthracosis (0/4). There is no evidence of malignancy. In addition, there is a fragment of normal-appearing skeletal muscle present.
- D. One slide is evaluated, demonstrating a bisected lymph node with extensive areas of anthracosis (0/1). There is no evidence of malignancy.
- E/EPC. Ten slides are evaluated showing sections from a lobe of lung with evidence of a moderately differentiated adenocarcinoma carcinoma, which measures 5.0 x 5.0 x 4.5 cm. The tumor shows diffuse areas of gland formation with prominent tumor necrosis, with evidence of lymphovascular space invasion. The vascular and bronchial margins are free of tumor, and the lesion is present approximately 1.0 mm beneath the inked pleural surface (slide E4). The surrounding lung parenchyma shows emphysematous changes with areas of congestion. In addition, two intraparenchymal lymph nodes are evaluated with no evidence of malignancy. However, evaluation of six hilar lymph nodes demonstrates evidence of metastatic carcinoma in one of the six lymph nodes evaluated.
- F. One slide is evaluated, demonstrating fragments of two lymph nodes with extensive areas of anthracosis (0/2). There is no evidence of malignancy.
- [REDACTED]

==== FINAL DIAGNOSIS: =====

- A. LYMPH NODE, INFERIOR PULMONARY LIGAMENT, BIOPSY: ANTHRACOSIS WITH NO EVIDENCE OF MALIGNANCY (0/1)
- B. LYMPH NODES, HILAR, BIOPSY: ANTHRACOSIS WITH NO EVIDENCE OF MALIGNANCY (0/5)
- C. LYMPH NODES, TRACHEOBRONCHIAL ANGLE, BIOPSY: ANTHRACOSIS WITH NO EVIDENCE OF MALIGNANCY (0/4)
- D. LYMPH NODE, SUBCARINAL, BIOPSY: ANTHRACOSIS WITH NO EVIDENCE OF MALIGNANCY (0/1)
- E/EPC. LUNG, RIGHT UPPER LOBE, LOBECTOMY:
- 1. HISTOLOGIC TYPE: ADENOCARCINOMA
- 2. HISTOLOGIC GRADE: G2, MODERATELY DIFFERENTIATED
- 3. EXTENT OF INVASION: pT2 (TUMOR SIZE 5.0 X 5.0 X 4.5 CM)
- 4. MARGINS: UNINVOLVED BY TUMOR

[page 4 of 4]
-
-
- 5. BLOOD/LYMPHATIC VESSEL INVASION: POSITIVE
- 6. REGIONAL LYMPH NODES: pN1 METASTATIC ADENOCARCINOMA PRESENT IN
1 OF 22 LYMPH NODES EVALUATED (1/22)
- 7. DISTANT METASTASIS: PMX; CANNOT BE ASSESSED
- 8. ADDITIONAL PATHOLOGIC FINDINGS: EMPHYSEMATOUS CHANGES WITH
PULMONARY CONGESTION
- F. LYMPH NODES, PROXIMAL BRONCHIAL, BIOPSY: ANTHRACOSIS WITH NO
EVIDENCE OF MALIGNANCY (0/2)

COMMENT: This case was discussed at the daily surgical pathology conference
on [REDACTED] and consensus of the diagnosis was reached.

A-MALIGNANT
[REDACTED]

Source: NCI Genomic Data Commons file f0e6163f-e604-499e-a509-cd6ee31c9d1c (TCGA-55-1596.200CCD8B-B3DC-4E3F-8C1E-ED9FA31AE9DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).